MMRF case MMRF_2074 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7e94e803-d2d4-477b-90c5-b48e342b581d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,388 days); ISS stage: II; Days to last known disease status: 974 days (2.7 years); Days to last follow up: 974 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 67 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 302 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -25 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 45.1 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.1 µg/mL; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 9.3 g/dL; Glucose 8.09 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 78: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.385 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.143 mg/dL; Immunoglobulin G 3.64 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.68 mmol/L.
- Day 163 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.524 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.205 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 71.6 ×10⁹/L; Absolute Neutrophil 63.7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 239 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.063 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.105 mg/dL; Immunoglobulin G 4.75 g/L; Immunoglobulin A 0.706 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.67 mmol/L.
- Day 323 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.039 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.068 mg/dL; Immunoglobulin G 4.07 g/L; Immunoglobulin A 0.482 g/L; Immunoglobulin M 0.199 g/L; Hemoglobin 9.73 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 6.82 mmol/L.
- Day 435 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.496 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.451 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 534 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.431 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.634 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.514 g/L; Immunoglobulin M 0.176 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 6 mmol/L.
- Day 616 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.572 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.594 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.551 g/L; Immunoglobulin M 0.203 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 675 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.636 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.452 mg/dL; Immunoglobulin G 5.54 g/L; Immunoglobulin A 0.509 g/L; Immunoglobulin M 0.254 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 7.21 mmol/L.
- Day 799 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.667 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.445 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.637 g/L; Immunoglobulin M 0.172 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 8.91 mmol/L.
- Day 840 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.645 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.584 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.701 g/L; Immunoglobulin M 0.205 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.71 mmol/L.
- Day 974 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.472 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.523 g/L; Immunoglobulin M 0.164 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.92 mmol/L.

Other clinical attributes
- Day -25: Weight: 75 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2074_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -25 days.
- Sample MMRF_2074_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -25 days.
